Somatic mutation profile of tumor specimen TCGA-R5-A7ZF-01A (aliquot TCGA-R5-A7ZF-01A-11D-A34U-08) from TCGA case TCGA-R5-A7ZF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.5 years (23,908 days).
Specimen TCGA-R5-A7ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62c99a1e-63d1-48de-9785-df7ccfdb27eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A7ZF-10A (Blood Derived Normal), aliquot TCGA-R5-A7ZF-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fbce054-6e97-4669-9fdc-3c156bf90ddd

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Nonsense Mutation 5, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3203C>A p.S1068* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs1554084848, CD160909, CM023010, COSV57330367, COSV57359180; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as rs1057518075, CM157982, COSV58585171, COSV58589931; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFP | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs780261526, COSV99890221; called by muse, mutect2, varscan2
- ATG4C | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100508451; called by muse, mutect2
- CHD4 | c.1792C>T p.R598C (on ENST00000357008 / NM_001363606.2; = p.R611C on NM_001273.5) | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV58897110; called by muse, mutect2
- CMTM5 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs781008966, COSV100198146; called by mutect2, varscan2
- CRELD2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs776108424, COSV100078183; called by muse, mutect2
- DCAF5 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV100432697; called by muse, mutect2, varscan2
- DLGAP4 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs367982678; called by muse, mutect2, varscan2
- DPY19L1 | c.1579G>A p.V527I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100204856; called by muse, mutect2, varscan2
- EHMT2 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs933835014, COSV64997963; called by muse, mutect2, varscan2
- ERO1B | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs966390978, COSV59242011; called by muse, mutect2, varscan2
- FCRL5 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.708); catalogued as rs1291571014, COSV62513115; called by muse, mutect2, varscan2
- GH2 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760386827, COSV60427954; called by muse, mutect2, varscan2
- IGSF1 | c.1907C>A p.P636Q | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV100812204; called by muse, mutect2
- KIF17 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs374159508; called by mutect2, varscan2
- L1CAM | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs201642622, COSV100649149; called by muse, mutect2, varscan2
- METAP1D | c.637T>C p.C213R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100250036; called by muse, mutect2, varscan2
- MMP16 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV99689548; called by muse, mutect2
- MUC16 | c.12304G>A p.A4102T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs746135164, COSV101197953; called by muse, mutect2, varscan2
- NCOR2 | c.6653G>A p.G2218D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); catalogued as COSV100657707; called by muse, mutect2, varscan2
- NR1D2 | c.1541C>G p.A514G | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100437550; called by muse, mutect2
- OSBPL11 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749695944, COSV99954406; called by muse, mutect2, varscan2
- PCDHB7 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782388523, COSV50763014; called by muse, mutect2, varscan2
- PIK3CG | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs370152741; called by muse, mutect2, varscan2
- PTPRU | c.3529C>T p.R1177W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs761647543, COSV100113375; called by muse, varscan2
- RO60 | c.677T>G p.L226* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as COSV100814418; called by muse, mutect2
- SALL1 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs775499747, COSV51754088, COSV99179121; called by muse, mutect2, varscan2
- SLC35F4 | c.1043T>C p.V348A (on ENST00000339762 / NM_001352015.2; = p.V312A on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100334062; called by muse, mutect2
- SLITRK2 | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as COSV100158040; called by muse, mutect2, varscan2
- SMAD4 | c.396C>A p.H132Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100748078, COSV61685812; called by muse, mutect2, varscan2
- SMARCC2 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 11/135 reads (8%) | catalogued as COSV99911703; called by muse, mutect2
- TBC1D15 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs756973108, COSV59847746; called by muse, mutect2, varscan2
- UGT3A2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV99236674; called by muse, mutect2
- UNC5D | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1214148843, COSV99777451; called by muse, mutect2
- VARS2 | c.2571G>A p.M857I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100423007; called by muse, mutect2, varscan2
- VPS13D | c.12538G>A p.G4180S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs552663711, COSV50633290, COSV99167778; called by muse, mutect2, varscan2
- NEK9 | c.1720_1728del p.I574_H576del | In Frame Del (DEL) | VAF 39/140 reads (28%) | called by mutect2, pindel, varscan2
- RNF111 | c.2033_2038del p.P678_P679del | In Frame Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- CMKLR1 | c.549G>A p.L183= (on ENST00000312143 / NM_001142344.2; = p.L181= on NM_004072.3) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1406357066, COSV100379545; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1917G>A p.V639= | Silent (SNP) | VAF 16/126 reads (13%) | called by mutect2, varscan2
- ITPR3 | c.5529G>A p.S1843= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs772326452, COSV65407185; called by muse, mutect2, varscan2
- LAMA1 | c.5235A>G p.V1745= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV101057134; called by muse, mutect2, varscan2
- MARCHF7 | c.111T>C p.Y37= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99373966; called by muse, mutect2
- NCAPD2 | c.2745C>T p.P915= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs774397972, COSV100217342; called by muse, mutect2, varscan2
- PLXNA2 | c.2013C>A p.R671= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100885674; called by muse, mutect2
- POU3F4 | c.360G>A p.P120= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV64537689; called by muse, mutect2, varscan2
- PRUNE2 | c.2943C>T p.D981= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs775573390, COSV65038796; called by muse, mutect2, varscan2
- RANBP2 | c.7044A>G p.Q2348= | Silent (SNP) | VAF 62/529 reads (12%) | catalogued as rs747041477, COSV51704364; called by muse, mutect2, varscan2
- SELENON | c.492T>C p.P164= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100823552; called by muse, mutect2, varscan2
- SEPTIN9 | c.819G>A p.P273= (on ENST00000427177 / NM_001113491.2; = p.P255= on NM_006640.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs751622773, COSV100218385; ClinVar: likely benign; called by muse, mutect2
- SLAMF6 | c.93C>T p.N31= | Silent (SNP) | VAF 36/231 reads (16%) | catalogued as rs561886814, COSV63587213; called by muse, mutect2, varscan2
- SPARC | c.483C>T p.T161= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs376445735, COSV50561843; called by muse, mutect2, varscan2
- TRIM8 | c.858G>A p.L286= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100193343; called by muse, mutect2, varscan2
- ZNF835 | c.270G>T p.P90= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV73379322, COSV73379564; called by muse, mutect2, varscan2
- CD300LD | chr17:74592560 G>A | 5'Flank (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
